Somatic mutation profile of tumor specimen C3L-01051-02 (aliquot CPT0123650009) from CPTAC case C3L-01051, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.8 years (22,192 days).
Specimen C3L-01051-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0dae278-0eb0-485d-9029-53a5a2a0c346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01051-31 (Blood Derived Normal), aliquot CPT0124870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b8429e3-5590-42a9-9923-e4d15fdb6b45

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Nonsense Mutation 3, Intron 3, RNA 3, In Frame Del 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 59/338 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 85/543 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520002, CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.706G>C p.G236R | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1386555857; called by muse, mutect2, varscan2
- CALB1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); catalogued as rs761899367; called by muse, mutect2, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 58/509 reads (11%) | catalogued as rs587782206; called by pindel, varscan2*
- CTNND2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 30/730 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); catalogued as rs1203316922; called by muse, mutect2
- DENND1A | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.844); catalogued as rs1313347212; called by mutect2, varscan2
- FCER1A | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV63667458, COSV63668419; called by muse, mutect2, varscan2
- FSCN1 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs150576558; called by muse, mutect2, varscan2
- GP9 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 74/922 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs763418097, COSV56624094; called by muse, mutect2
- KMT2C | c.13199G>A p.R4400Q | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51466658, COSV99031036; called by muse, mutect2, varscan2
- LRCH3 | c.1962_1964del p.E655del | In Frame Del (DEL) | VAF 48/236 reads (20%) | catalogued as rs759920668; called by pindel, varscan2
- LRP1B | c.5960G>A p.R1987H | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202025670, COSV67264252; called by muse, mutect2, varscan2
- LRRC34 | c.1073T>C p.V358A (on ENST00000446859 / NM_001172779.2; = p.V326A on NM_153353.5) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs543612719; called by muse, mutect2, varscan2
- OTOP3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1208933869; called by muse, mutect2, varscan2
- PCDH10 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as rs1208608369, COSV99994601; called by muse, mutect2
- RNF103 | c.1769G>A p.R590K | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV52893523; called by muse, mutect2
- SCN1A | c.2378C>T p.T793M (on ENST00000303395 / NM_001202435.3; = p.T782M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs762038032, CM126546, COSV100321456; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SPTBN5 | c.5788C>T p.R1930* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as rs771424817; called by muse, mutect2
- TDRD6 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV60174750; called by muse, mutect2, varscan2
- TENM2 | c.5465G>A p.R1822H (on ENST00000518659 / NM_001122679.2; = p.R1583H on NM_001080428.3) | Missense Mutation (SNP) | VAF 50/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69124662; called by muse, mutect2, varscan2
- TRBC2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 85/481 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs544245790; called by muse, mutect2, varscan2
- TREM2 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 158/811 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs368921728; called by muse, mutect2, varscan2
- TRPM8 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1167199351; called by muse, mutect2, varscan2
- TSGA10IP | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 15/169 reads (9%) | catalogued as rs758452043, COSV73245228; called by muse, mutect2
- TTBK1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs374064146; called by muse, mutect2
- ADAMTS20 | c.763A>C p.I255L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.5483T>A p.L1828* | Nonsense Mutation (SNP) | VAF 20/313 reads (6%) | called by muse, mutect2
- BRIP1 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); called by mutect2, varscan2
- EOGT | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GARNL3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- GPAT4 | c.702G>C p.R234S | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR6C4 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- POLR1C | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 598/1604 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- S1PR1 | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPTIN8 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC40A1 | c.472T>G p.W158G | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- VSIG10L | c.2329A>T p.I777F | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR41 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB20 | c.1864A>G p.I622V (on ENST00000474710 / NM_001164342.2; = p.I549V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ZNF574 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2
- APP | c.414G>A p.Q138= | Silent (SNP) | VAF 38/396 reads (10%) | catalogued as COSV100696279; called by muse, mutect2
- CDH8 | c.588C>T p.D196= | Silent (SNP) | VAF 13/388 reads (3%) | catalogued as COSV54864778; called by muse, mutect2
- DYSF | c.600C>T p.I200= | Silent (SNP) | VAF 143/949 reads (15%) | called by muse, mutect2, varscan2
- EBI3 | c.249G>C p.T83= | Silent (SNP) | VAF 37/191 reads (19%) | called by muse, mutect2, varscan2
- EFL1 | c.2508A>T p.L836= | Silent (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- FEZ2 | c.900C>T p.G300= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, varscan2
- IL18RAP | c.1299G>A p.L433= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- KNTC1 | c.5601A>T p.V1867= | Silent (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- KRT27 | c.888C>T p.A296= | Silent (SNP) | VAF 42/320 reads (13%) | called by muse, varscan2
- NYAP2 | c.1218C>T p.A406= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- PAN3 | c.258C>A p.V86= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs746350264; called by muse, mutect2, varscan2
- PSD | c.1359C>T p.P453= | Silent (SNP) | VAF 43/261 reads (16%) | catalogued as rs745853601; called by muse, mutect2, varscan2
- SLC10A2 | c.990G>A p.T330= | Silent (SNP) | VAF 35/296 reads (12%) | catalogued as rs148791669, COSV55361238; called by muse, mutect2, varscan2
- SOGA1 | c.1095C>T p.T365= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as rs371451776; called by muse, mutect2
- SPATA31D1 | c.3084T>C p.G1028= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV100782742; called by muse, mutect2, varscan2
- WNK2 | c.4710G>A p.S1570= (on ENST00000297954 / NM_001282394.1; = p.S1533= on NM_006648.3) | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs750204095, COSV52950151; called by muse, mutect2, varscan2
- ABCC6P1 | n.1194A>G | RNA (SNP) | VAF 33/646 reads (5%) | catalogued as rs780288034; called by muse, mutect2
- AC024940.1 | n.3808G>A | RNA (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
- DDX31 | c.767+61C>T | Intron (SNP) | VAF 13/228 reads (6%) | catalogued as rs891885299; called by muse, mutect2
- FAM90A27P | n.1051C>T | RNA (SNP) | VAF 72/592 reads (12%) | catalogued as rs1441209692; called by muse, mutect2, varscan2
- HARS2 | c.-6C>T | 5'UTR (SNP) | VAF 93/645 reads (14%) | catalogued as rs1384385519; called by muse, mutect2, varscan2
- SLC2A14 | c.88-6975C>T | Intron (SNP) | VAF 28/306 reads (9%) | catalogued as rs1044465148; called by muse, mutect2
- ST6GAL1 | c.706-10C>T | Intron (SNP) | VAF 21/479 reads (4%) | called by muse, mutect2
